Somatic mutation profile of tumor specimen MP2PRT-PAUCUZ-TMP1-A (aliquot MP2PRT-PAUCUZ-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUCUZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,920 days).
Specimen MP2PRT-PAUCUZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a3f3fce-4dd0-4765-95f3-0e13798b650c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCUZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCUZ-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b95ded20-b0a5-4276-a96c-758a34688903

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 152/328 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALDH1B1 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 146/305 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs761929369; called by muse, mutect2, varscan2
- HSPA4L | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs374327031; called by muse, mutect2, varscan2
- PIP5KL1 | c.1144G>A p.A382T (on ENST00000388747 / NM_001135219.2; = p.A179T on NM_173492.1) | Missense Mutation (SNP) | VAF 207/489 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1359915332; called by muse, mutect2, varscan2
- TRPC1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV104383688; called by muse, mutect2, varscan2
- CNOT1 | c.5839G>A p.V1947M | Missense Mutation (SNP) | VAF 28/319 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2
- ATP8A2 | c.1992C>T p.Y664= | Silent (SNP) | VAF 98/247 reads (40%) | catalogued as rs746325167, COSV54952847; called by muse, mutect2, varscan2
- PABPC4L | c.387G>C p.V129= | Silent (SNP) | VAF 160/502 reads (32%) | called by muse, mutect2, varscan2
- SASH1 | c.*1019C>T | 3'UTR (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
